MMRF case MMRF_2836 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/75ea9bc1-b724-4ebc-b4e6-33dbc694aed1

Demographics
Sex at birth: male; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.3 years (20,917 days); ISS stage: II; Days to last known disease status: 161 days; Days to last follow up: 161 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 166 days; Days to treatment end: 166 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -24, day 161.

Molecular and laboratory tests (values rounded to 3 significant figures where GDC's unit conversion carried more)
- M Protein 0.39 g/dL.
- Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL.
- Calcium 2.57 mmol/L.
- Absolute Neutrophil 11.1 ×10⁹/L.
- Hemoglobin 6.07 mmol/L.
- Creatinine 76.9 µmol/L.
- Platelets 209 ×10⁹/L.
- Lactate Dehydrogenase 5.75 µkat/L.
- Albumin 33.2 g/L.
- Beta 2 Microglobulin 2.7 µg/mL.
- Serum Free Immunoglobulin Light Chain, Lambda 302 mg/dL.

Other clinical attributes
- Day -24: Weight: 66 kg; Height: 170 cm.

Biospecimens (2 samples)
- Sample MMRF_2836_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -24 days.
- Sample MMRF_2836_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -24 days.
